Somatic mutation profile of tumor specimen TCGA-E1-A7YM-01A (aliquot TCGA-E1-A7YM-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YM, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 63.7 years (23,263 days).
Specimen TCGA-E1-A7YM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e669f78-b750-4315-b56f-be746bd8e5e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YM-10A (Blood Derived Normal), aliquot TCGA-E1-A7YM-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93db98ff-357e-4ad0-bcc5-f9a33df2a983

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 30, Silent 12, Splice Region 2, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2
- RB1 | c.951_954del p.S318Nfs*13 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs1566194323; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SETD2 | c.4873C>T p.R1625C | Missense Mutation (SNP) | VAF 13/130 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57429702; called by muse, mutect2, varscan2
- ABCC4 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs763493372, COSV65313204; called by muse, mutect2, varscan2
- ADGRD1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs144030317; called by muse, mutect2, varscan2
- ALPP | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs753036535, COSV67395940; called by mutect2, varscan2
- ATP11A | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV52107129; called by muse, mutect2, varscan2
- BBS9 | c.1714G>A p.D572N (on ENST00000242067 / NM_001348036.1; = p.D532N on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV99630262; called by muse, mutect2, varscan2
- BMP10 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV54897350; called by muse, mutect2, varscan2
- CABS1 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as rs139939232; called by muse, mutect2, varscan2
- CACNA1D | c.3406A>G p.I1136V (on ENST00000350061 / NM_001128840.3; = p.I1156V on NM_000720.4) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99860152; called by muse, mutect2, varscan2
- CALHM4 | c.928A>G p.I310V (on ENST00000368596 / NM_001366078.1; = p.I124V on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV100888909; called by muse, mutect2, varscan2
- DBH | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs766166337, COSV55039535; called by muse, mutect2, varscan2
- DMXL1 | c.3049A>G p.I1017V | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs541463868, COSV100225039; called by muse, mutect2, varscan2
- DNAH9 | c.12547G>A p.A4183T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375302076; called by muse, mutect2, varscan2
- DOCK2 | c.4439G>A p.R1480H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764242211, COSV56972447; called by muse, mutect2, varscan2
- FGF16 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs782731399, COSV71546165; called by muse, mutect2, varscan2
- IGF2BP1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99289119; called by muse, mutect2, varscan2
- IL1RL1 | c.1165T>C p.S389P | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as COSV99294575; called by muse, mutect2, varscan2
- KCNA5 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs779699586, COSV52906823; called by muse, mutect2, varscan2
- KL | c.2768C>T p.P923L | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs748304951, COSV101199215; called by muse, mutect2, varscan2
- LIN52 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs765460206, COSV101625001; called by muse, mutect2, varscan2
- MAG | c.914G>A p.C305Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100728071; called by muse, mutect2, varscan2
- MICB | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as rs751152310, COSV52858225; called by muse, mutect2, varscan2
- MORN5 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.309); catalogued as COSV101056001; called by muse, mutect2, varscan2
- NDUFS1 | c.870C>A p.T290= | Splice Region (SNP) | VAF 18/80 reads (23%) | catalogued as rs773850118, COSV99261516; called by muse, mutect2, varscan2
- NGEF | c.1391C>T p.T464M | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs1372115773, COSV50949000; called by muse, mutect2, varscan2
- PYHIN1 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs568353781, COSV63722127, COSV63722532; called by muse, mutect2
- SERINC2 | c.352G>A p.V118M (on ENST00000373709 / NM_178865.5; = p.V122M on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs782816945, COSV101037138; called by muse, mutect2, varscan2
- TEX15 | c.2483G>A p.G828D (on ENST00000256246; = p.G1211D on NM_001350162.2) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.33); catalogued as COSV99822178; called by muse, mutect2, varscan2
- UBE2J1 | c.681C>T p.Y227= | Splice Region (SNP) | VAF 16/77 reads (21%) | catalogued as rs199520794; called by muse, mutect2, varscan2
- VIT | c.1882G>A p.V628I (on ENST00000389975 / NM_001177969.1; = p.V643I on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs368417581; called by muse, mutect2, varscan2
- ZBED9 | c.950G>C p.S317T | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.577); catalogued as COSV101509404; called by muse, mutect2, varscan2
- LAYN | c.1088C>T p.P363L (on ENST00000375615 / NM_001258390.1; = p.P355L on NM_178834.5) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- SMG1 | c.5017_5019del p.L1673del | In Frame Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- BTN2A2 | c.1560C>T p.H520= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100760601; called by muse, mutect2, varscan2
- DOCK8 | c.831C>T p.F277= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as rs752581736, COSV66632977; called by muse, mutect2, varscan2
- MUC2 | c.1635G>A p.L545= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1233955533; called by muse, mutect2, varscan2
- MYO9A | c.51A>G p.T17= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as rs754735768, COSV100614377; called by muse, mutect2, varscan2
- MYOF | c.5442C>T p.D1814= | Silent (SNP) | VAF 53/188 reads (28%) | catalogued as COSV100826149; called by muse, mutect2, varscan2
- OR3A3 | c.492C>T p.N164= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as rs1354761038, COSV99351494; called by muse, mutect2
- OR4C12 | c.282G>A p.G94= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as COSV100078701; called by muse, mutect2, varscan2
- PCDHA10 | c.1440C>T p.D480= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV56500259; called by muse, mutect2, varscan2
- RAD51AP2 | c.1425G>A p.T475= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs759984947, COSV101208419; called by muse, mutect2, varscan2
- RBMS3 | c.1128G>A p.G376= (on ENST00000383767 / NM_001003793.3; = p.G360= on NM_014483.3) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99824421; called by muse, mutect2
- TMOD2 | c.657A>G p.A219= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as COSV99988100; called by muse, mutect2, varscan2
- ZNF311 | c.1555A>C p.R519= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV101014284; called by muse, mutect2, varscan2
